Somatic mutation profile of tumor specimen TCGA-FC-A5OB-01A (aliquot TCGA-FC-A5OB-01A-11D-A29Q-08) from TCGA case TCGA-FC-A5OB, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 53.1 years (19,413 days).
Specimen TCGA-FC-A5OB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bd450869-df37-4086-8f8b-cd826c9d05de.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FC-A5OB-10A (Blood Derived Normal), aliquot TCGA-FC-A5OB-10A-01D-A29Q-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f9d20ca8-242a-4f7d-bac6-f0134baa0633

The open-access MAF lists 22 somatic variants for this specimen: 16 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 13, Silent 6, Frame Shift Del 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CRLF1 | c.1231T>C p.S411P | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV62260766; called by muse, mutect2, varscan2
- EIF5A2 | c.197G>A p.G66D | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.373); catalogued as rs865793416, COSV55543343; called by muse, mutect2
- FKBP10 | c.472G>T p.V158L | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as COSV58637436; called by muse, mutect2, varscan2
- FMN1 | c.2489C>A p.P830H (on ENST00000616417 / NM_001277313.2; = p.P607H on NM_001103184.4) | Missense Mutation (SNP) | VAF 98/233 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57926136; called by muse, mutect2, varscan2
- HERC2 | c.13745G>A p.G4582E | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV55331479; called by muse, mutect2, varscan2
- NR1I3 | c.96G>C p.K32N | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63468502; called by muse, mutect2, varscan2
- NXN | c.737A>G p.Y246C | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV61097765; called by muse, mutect2, varscan2
- PTPN12 | c.426dup p.C143Mfs*2 | Frame Shift Ins (INS) | VAF 24/82 reads (29%) | catalogued as rs1377430344; called by mutect2, pindel, varscan2
- RANBP17 | c.2296A>G p.T766A | Missense Mutation (SNP) | VAF 54/125 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as rs148262159; called by muse, mutect2, varscan2
- RIMBP2 | c.2140G>T p.D714Y | Missense Mutation (SNP) | VAF 8/177 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as COSV55476714; called by muse, mutect2
- SPEG | c.2740C>T p.R914W | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1240036119, COSV56665135; called by muse, mutect2, varscan2
- SRGAP1 | c.1693G>A p.A565T | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.61); PolyPhen benign (0.012); catalogued as COSV61899841; called by muse, mutect2, varscan2
- SSTR3 | c.1007G>A p.R336H | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.277); catalogued as rs143937169; called by muse, mutect2, varscan2
- TSGA13 | c.400C>T p.Q134* | Nonsense Mutation (SNP) | VAF 4/44 reads (9%) | catalogued as COSV58405828; called by muse, mutect2
- ZNF714 | c.299A>T p.K100I | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.046); catalogued as COSV52513195; called by muse, mutect2, varscan2
- BCHE | c.1739del p.N580Ifs*3 | Frame Shift Del (DEL) | VAF 11/18 reads (61%) | called by mutect2, varscan2
- BUB1B | c.2229G>A p.L743= | Silent (SNP) | VAF 39/101 reads (39%) | catalogued as COSV55014034; called by muse, mutect2, varscan2
- CACNA1F | c.3150A>C p.G1050= | Silent (SNP) | VAF 13/14 reads (93%) | catalogued as COSV100545478, COSV59905234; called by muse, mutect2, varscan2
- MAG | c.1026G>A p.T342= | Silent (SNP) | VAF 26/76 reads (34%) | catalogued as rs200660504, COSV62700616; called by muse, mutect2, varscan2
- OR2AE1 | c.195G>A p.Q65= | Silent (SNP) | VAF 26/64 reads (41%) | catalogued as COSV60390559; called by muse, mutect2
- PTX4 | c.375G>A p.L125= (on ENST00000447419 / NM_001328608.2; = p.L120= on NM_001013658.1) | Silent (SNP) | VAF 34/84 reads (40%) | catalogued as COSV53517698; called by muse, mutect2, varscan2
- SGO1 | c.1219A>C p.R407= | Silent (SNP) | VAF 9/112 reads (8%) | catalogued as COSV55424235; called by muse, mutect2
